Somatic mutation profile of tumor specimen 0DWM1F from CCDI case PBCPIJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 0.4 years (136 days).
Specimen 0DWM1F: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 21718ad1-0b59-4854-909f-ee2daf6ceab5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWLYU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/533480a8-524b-4cce-af11-12ecacedd26e

The open-access MAF lists 18 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 4, Splice Site 3, Intron 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA1 | c.2878G>A p.G960S | Missense Mutation (SNP) | VAF 39/1737 reads (2%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.531); catalogued as rs1555588796; ClinVar: uncertain significance; called by muse, mutect2
- DDAH1 | c.52G>C p.V18L | Missense Mutation (SNP) | VAF 57/499 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as rs897977961; called by muse, mutect2, varscan2
- TTC6 | c.805G>T p.D269Y (on ENST00000267368; = p.D1635Y on NM_001310135.3) | Missense Mutation (SNP) | VAF 94/1150 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1316039061; called by muse, mutect2
- AHNAK | c.2379C>A p.S793R | Missense Mutation (SNP) | VAF 62/712 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.017); called by muse, mutect2
- HCN1 | c.863C>A p.T288K | Missense Mutation (SNP) | VAF 301/876 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- ITGAL | c.61+1G>C p.X21_splice | Splice Site (SNP) | VAF 135/404 reads (33%) | called by muse, mutect2, varscan2
- MMP10 | c.566G>T p.G189V | Missense Mutation (SNP) | VAF 56/1303 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- OR2F1 | c.388C>A p.L130M | Missense Mutation (SNP) | VAF 85/775 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PHYHIPL | c.388dup p.Y130Lfs*13 | Frame Shift Ins (INS) | VAF 210/1383 reads (15%) | called by mutect2, varscan2
- PTPRQ | c.6123+1G>T p.X2041_splice (on ENST00000616559; = p.X2008_splice on NM_001145026.2) | Splice Site (SNP) | VAF 118/1149 reads (10%) | called by muse, mutect2, varscan2
- TNRC18 | c.2329C>A p.L777I | Missense Mutation (SNP) | VAF 40/523 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2
- TRIM7 | c.619-1G>T p.X207_splice | Splice Site (SNP) | VAF 34/1410 reads (2%) | called by muse, mutect2
- CPA1 | c.642C>T p.D214= | Silent (SNP) | VAF 110/1023 reads (11%) | called by muse, varscan2
- MYPN | c.1053G>A p.S351= | Silent (SNP) | VAF 70/786 reads (9%) | catalogued as rs371306075; called by muse, mutect2
- OR10H1 | c.669G>T p.V223= | Silent (SNP) | VAF 37/427 reads (9%) | called by muse, mutect2, varscan2
- TANC2 | c.1980A>T p.T660= | Silent (SNP) | VAF 344/1329 reads (26%) | called by muse, mutect2, varscan2
- MVD | c.603+76G>A | Intron (SNP) | VAF 77/201 reads (38%) | called by muse, mutect2, varscan2
- ZC3H18 | c.1206+29A>T | Intron (SNP) | VAF 10/253 reads (4%) | catalogued as rs1321661955; called by muse, mutect2
